Somatic mutation profile of tumor specimen 0DIOKE from CCDI case PBBVKH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.2 years (4,806 days).
Specimen 0DIOKE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ee3f254-664e-4c54-9384-2ac374f8fd5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIOJX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74a1c79a-6e0f-43af-85bb-55a7756ae583

The open-access MAF lists 35 somatic variants for this specimen: 22 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 9, Intron 3, Splice Site 2, Splice Region 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 279/557 reads (50%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LRRC55 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 21/645 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as rs1295740885; called by muse, mutect2
- MAGEB1 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 177/758 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs779578367; called by muse, mutect2, varscan2
- NSUN2 | c.1818+1G>A p.X606_splice | Splice Site (SNP) | VAF 226/621 reads (36%) | catalogued as rs762632551; called by muse, mutect2
- PDGFRA | c.1154A>T p.K385M | Missense Mutation (SNP) | VAF 237/611 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57264818; called by muse, mutect2, varscan2
- PDGFRA | c.2525A>G p.D842G | Missense Mutation (SNP) | VAF 297/809 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57264120; called by muse, mutect2, varscan2
- PIK3CG | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 190/554 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as rs1463041855; called by muse, mutect2, varscan2
- TENM1 | c.5695C>T p.R1899W | Missense Mutation (SNP) | VAF 214/676 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64432948; called by muse, mutect2, varscan2
- DDB2 | c.1235G>A p.G412D | Missense Mutation (SNP) | VAF 101/296 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX4 | c.1237G>C p.V413L | Missense Mutation (SNP) | VAF 27/780 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0.027); called by muse, mutect2
- DNAAF3 | c.992G>T p.G331V (on ENST00000524407 / NM_001256715.2; = p.G378V on NM_178837.4) | Missense Mutation (SNP) | VAF 273/739 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- JKAMP | c.638T>C p.F213S (on ENST00000554271 / NM_001284201.1; = p.F199S on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/446 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2
- KLK3 | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 109/298 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- MAGEA1 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 173/543 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- MEST | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 116/270 reads (43%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- PPM1D | c.1387_1406del p.G463Rfs*6 | Frame Shift Del (DEL) | VAF 462/931 reads (50%) | called by mutect2, varscan2
- SART1 | c.2357T>G p.L786R | Missense Mutation (SNP) | VAF 192/512 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- SLK | c.3321+1G>A p.X1107_splice | Splice Site (SNP) | VAF 12/406 reads (3%) | called by muse, mutect2
- SPATA48 | c.197A>T p.K66I | Missense Mutation (SNP) | VAF 278/697 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.26971A>G p.R8991G (on ENST00000591111; = p.R8064G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 143/393 reads (36%) | PolyPhen benign (0.163); called by muse, mutect2, varscan2
- VPS72 | c.117G>A p.E39= | Splice Region (SNP) | VAF 152/598 reads (25%) | called by muse, mutect2, varscan2
- ZMAT3 | c.77G>A p.R26K | Missense Mutation (SNP) | VAF 276/782 reads (35%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- C19orf38 | c.228C>T p.G76= | Silent (SNP) | VAF 85/273 reads (31%) | catalogued as rs996970135; called by muse, mutect2, varscan2
- CASZ1 | c.5226G>A p.A1742= | Silent (SNP) | VAF 117/306 reads (38%) | called by muse, mutect2, varscan2
- CUEDC1 | c.1086C>T p.H362= | Silent (SNP) | VAF 105/487 reads (22%) | catalogued as rs750770869, COSV64227489; called by muse, mutect2, varscan2
- DLG3 | c.93C>A p.G31= | Silent (SNP) | VAF 154/427 reads (36%) | called by muse, mutect2, varscan2
- E2F3 | c.714C>T p.N238= | Silent (SNP) | VAF 160/435 reads (37%) | catalogued as rs763278356, COSV60896810; called by muse, mutect2, varscan2
- HMCN2 | c.2475T>A p.P825= | Silent (SNP) | VAF 194/525 reads (37%) | called by muse, mutect2, varscan2
- KCNG1 | c.174C>T p.P58= | Silent (SNP) | VAF 154/555 reads (28%) | catalogued as rs1431855834; called by muse, mutect2, varscan2
- LRRC23 | c.399G>T p.L133= | Silent (SNP) | VAF 238/696 reads (34%) | called by muse, mutect2, varscan2
- MAGEA8 | c.270T>C p.N90= | Silent (SNP) | VAF 32/786 reads (4%) | catalogued as rs1557370920; called by muse, mutect2
- C1orf141 | c.347-6952C>T | Intron (SNP) | VAF 143/412 reads (35%) | called by muse, mutect2, varscan2
- DAZAP1 | c.1048+53C>T | Intron (SNP) | VAF 95/233 reads (41%) | catalogued as rs1436673505; called by muse, mutect2, varscan2
- H2BC13 | c.*71T>G | 3'UTR (SNP) | VAF 11/101 reads (11%) | called by muse, mutect2
- RUSC1 | c.-86-255C>T | Intron (SNP) | VAF 74/1184 reads (6%) | called by muse, mutect2
